CCDI case PBBUPC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/1c38caad-bed4-47a2-bd43-bb2753a6dd79

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 15.8 years (5,766 days).

Biospecimens (2 samples)
- Sample 0DITSB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DITT2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
